Somatic mutation profile of tumor specimen C3L-02384-01 (aliquot CPT0127980006) from CPTAC case C3L-02384, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 81.4 years (29,731 days).
Specimen C3L-02384-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9c7591d-1bd3-4842-b6ab-2befa8e1edb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02384-74 (Blood Derived Normal), aliquot CPT0128070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/079c2694-fc76-4849-93fc-87378bc1aa4f

The open-access MAF lists 92 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 19, Intron 6, Nonsense Mutation 4, RNA 3, 3'UTR 2, Splice Site 2, 3'Flank 2, Splice Region 2, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 40/297 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 265/328 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD42 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.114); catalogued as COSV52616137; called by muse, mutect2
- ARHGEF17 | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 101/283 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs775863972, COSV55232376, COSV55233388; called by muse, mutect2, varscan2
- ARIH2 | c.539-1G>A p.X180_splice | Splice Site (SNP) | VAF 16/256 reads (6%) | catalogued as COSV100711416; called by muse, mutect2
- CLEC14A | c.507C>A p.Y169* | Nonsense Mutation (SNP) | VAF 12/274 reads (4%) | catalogued as rs1274083821; called by muse, mutect2
- CRACD | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.081); catalogued as rs1410275568; called by muse, mutect2
- CTPS1 | c.1640C>G p.S547C | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs772675294; called by muse, mutect2
- CUL9 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs1562010986, COSV99334497; called by muse, mutect2, varscan2
- GID8 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 95/419 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV99824195; called by muse, mutect2, varscan2
- GORASP1 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 103/242 reads (43%) | catalogued as rs1439933634; called by muse, mutect2, varscan2
- LGR6 | c.2011G>A p.V671I (on ENST00000367278 / NM_001017403.1; = p.V619I on NM_021636.3) | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs763458876, COSV99708143; called by muse, mutect2, varscan2
- MAN2B1 | c.1527C>T p.R509= | Splice Region (SNP) | VAF 46/374 reads (12%) | catalogued as rs1486751691, COSV99667246; called by muse, mutect2, varscan2
- MIDN | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99960423; called by muse, mutect2, varscan2
- MYC | c.176C>G p.P59R (on ENST00000377970; = p.P74R on NM_002467.6) | Missense Mutation (SNP) | VAF 59/97 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2, varscan2
- MYC | c.1073C>G p.T358R (on ENST00000377970; = p.T373R on NM_002467.6) | Missense Mutation (SNP) | VAF 133/227 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52374031; called by muse, mutect2, varscan2
- MYH11 | c.5435T>C p.F1812S | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs1567687648; called by muse, mutect2
- MYO1F | c.1375A>G p.S459G | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs1049722804; called by muse, mutect2
- NEB | c.3271G>C p.D1091H | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99423696; called by muse, mutect2, varscan2
- NPAS2 | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs1321439599; called by muse, mutect2, varscan2
- PTPRS | c.3694G>A p.D1232N | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.21); catalogued as rs752222706; called by muse, mutect2
- PXDNL | c.2278G>A p.G760S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1229996178; called by muse, mutect2, varscan2
- RGPD4 | c.2965A>G p.K989E | Missense Mutation (SNP) | VAF 40/649 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.306); catalogued as COSV100736421; called by muse, mutect2
- RNF41 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 16/472 reads (3%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.518); catalogued as rs903589499, COSV100560330; called by muse, mutect2
- RNF43 | c.531C>G p.Y177* | Nonsense Mutation (SNP) | VAF 414/463 reads (89%) | catalogued as COSV68457244; called by muse, mutect2, varscan2
- ROBO1 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.745); catalogued as COSV101517868; called by muse, mutect2, varscan2
- ZNF595 | c.1585A>G p.I529V | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs782592988; called by muse, mutect2
- ZNF721 | c.2018A>G p.N673S (on ENST00000338977; = p.N685S on NM_133474.4) | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.194); catalogued as rs782109285, COSV100167732; called by muse, mutect2, varscan2
- ATG2B | c.4658T>A p.V1553D | Missense Mutation (SNP) | VAF 40/448 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- CATSPERB | c.3046T>G p.L1016V | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- COMMD6 | c.54+7G>T | Splice Region (SNP) | VAF 62/148 reads (42%) | called by muse, mutect2, varscan2
- CTDSP2 | c.716_721del p.D239_M240del | In Frame Del (DEL) | VAF 168/327 reads (51%) | called by mutect2, pindel, varscan2
- DNAJC13 | c.3113T>C p.L1038P | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2
- FLRT3 | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBA3 | c.1240T>C p.Y414H | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GDPD4 | c.149T>A p.L50* | Nonsense Mutation (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
- GLYAT | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 67/269 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- GRINA | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- IARS2 | c.4C>G p.R2G | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IRF2BP2 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNG1 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTCL1 | c.2548T>G p.L850V (on ENST00000306329 / NM_001378206.1; = p.L490V on NM_015210.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAALAD2 | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 139/354 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NAT10 | c.2162+1G>A p.X721_splice | Splice Site (SNP) | VAF 11/183 reads (6%) | called by muse, mutect2
- NES | c.4162G>A p.E1388K | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); called by muse, mutect2
- NF1 | c.7016A>T p.E2339V (on ENST00000358273 / NM_001042492.3; = p.E2318V on NM_000267.3) | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2
- NFKBIE | c.695C>G p.P232R (on ENST00000275015; = p.P93R on NM_004556.3) | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2
- POLG | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- POLR1A | c.2176G>A p.G726S | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2
- PRKACB | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- RASAL2 | c.1793C>A p.T598N | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- RBBP6 | c.1863G>C p.Q621H | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SMARCAD1 | c.1902G>T p.K634N | Missense Mutation (SNP) | VAF 178/375 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMG7 | c.1995del p.P667Qfs*63 | Frame Shift Del (DEL) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- SOBP | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 19/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STARD9 | c.1431C>G p.S477R | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2
- TBC1D4 | c.767A>C p.E256A | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.184); called by muse, mutect2
- TCHHL1 | c.1110G>C p.K370N | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2
- TDRKH | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by muse, mutect2
- TSHZ3 | c.1360T>C p.S454P | Missense Mutation (SNP) | VAF 156/320 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRF2 | c.1380C>T p.S460= (on ENST00000296862 / NM_001368115.2; = p.S392= on NM_153839.7) | Silent (SNP) | VAF 11/238 reads (5%) | called by muse, mutect2
- ADGRF4 | c.33C>G p.L11= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- ATG2B | c.4659C>A p.V1553= | Silent (SNP) | VAF 39/442 reads (9%) | called by muse, mutect2
- CCN5 | c.618C>T p.T206= | Silent (SNP) | VAF 68/160 reads (43%) | called by muse, mutect2, varscan2
- CDH13 | c.936G>T p.V312= | Silent (SNP) | VAF 54/90 reads (60%) | called by muse, mutect2, varscan2
- DLG2 | c.2457C>A p.T819= | Silent (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- DNAH7 | c.11409C>T p.C3803= | Silent (SNP) | VAF 439/524 reads (84%) | catalogued as rs536343588; called by muse, mutect2, varscan2
- FAM160B2 | c.2217G>A p.P739= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs185880722, COSV99248802; called by muse, mutect2, varscan2
- IRAK3 | c.66C>G p.P22= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as rs1254422610; called by muse, mutect2
- MAGEC3 | c.645C>A p.I215= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV53580256; called by muse, mutect2, varscan2
- MTMR11 | c.1194A>G p.R398= (on ENST00000439741 / NM_001145862.2; = p.R326= on NM_181873.3) | Silent (SNP) | VAF 71/175 reads (41%) | called by muse, mutect2, varscan2
- OTOL1 | c.954C>T p.V318= | Silent (SNP) | VAF 21/190 reads (11%) | called by muse, mutect2, varscan2
- RAB40B | c.606C>G p.S202= | Silent (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- RNF133 | c.510A>T p.G170= | Silent (SNP) | VAF 18/300 reads (6%) | called by muse, mutect2
- SCML4 | c.1185G>A p.K395= | Silent (SNP) | VAF 145/375 reads (39%) | called by muse, mutect2, varscan2
- SLC20A1 | c.744C>T p.F248= | Silent (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- SLITRK5 | c.1803C>T p.T601= | Silent (SNP) | VAF 20/220 reads (9%) | catalogued as COSV61521076, COSV61521110; called by muse, mutect2
- SUSD2 | c.513C>T p.T171= | Silent (SNP) | VAF 42/305 reads (14%) | catalogued as rs1454619423; called by muse, mutect2, varscan2
- VAC14 | c.966C>T p.N322= | Silent (SNP) | VAF 20/166 reads (12%) | catalogued as rs776361528, COSV55752790; called by muse, mutect2
- AC022748.1 | n.33C>T | RNA (SNP) | VAF 12/153 reads (8%) | catalogued as rs552805701; called by muse, mutect2
- ARHGAP27P2 | n.450G>C | RNA (SNP) | VAF 17/169 reads (10%) | catalogued as rs782605759; called by muse, mutect2
- C5orf60 | n.1688G>T | RNA (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- CORO1B | c.756+9C>G | Intron (SNP) | VAF 16/309 reads (5%) | called by muse, mutect2
- DENND2B | c.3380-432T>G | Intron (SNP) | VAF 65/157 reads (41%) | called by muse, mutect2, varscan2
- DST | c.4296+4932A>G | Intron (SNP) | VAF 11/265 reads (4%) | called by muse, mutect2
- DUSP13 | c.*736G>C | 3'UTR (SNP) | VAF 22/254 reads (9%) | called by muse, mutect2
- EPSTI1 | chr13:42888365 C>G | 3'Flank (SNP) | VAF 26/292 reads (9%) | catalogued as rs763326690, COSV100552604, COSV58048949; called by muse, mutect2
- F11 | c.1135+1372A>T | Intron (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- INKA2 | c.*3926C>G | 3'UTR (SNP) | VAF 10/103 reads (10%) | catalogued as rs1361101193; called by muse, mutect2
- KHDC1 | c.164-11C>G | Intron (SNP) | VAF 93/231 reads (40%) | called by muse, mutect2, varscan2
- KIR2DL3 | chr19:54755048 C>T | 3'Flank (SNP) | VAF 138/436 reads (32%) | catalogued as rs1426184955; called by muse, varscan2
- SSH3 | c.67-32C>A | Intron (SNP) | VAF 5/56 reads (9%) | catalogued as COSV57383786; called by muse, mutect2
